Somatic mutation profile of tumor specimen TCGA-AB-2816-03B (aliquot TCGA-AB-2816-03B-01W-0728-08) from TCGA case TCGA-AB-2816, project TCGA-LAML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myelomonocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 57.3 years (20,939 days).
Specimen TCGA-AB-2816-03B: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b831b331-7173-43a2-8387-74b41cb37ae8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AB-2816-11B (Solid Tissue Normal), aliquot TCGA-AB-2816-11B-01W-0728-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c36faad0-d8a4-48af-8c24-a3416df677fe

The open-access MAF lists 4 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, 5'Flank 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CLIP2 | c.3095G>A p.G1032D | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs868978492, COSV56277826; called by muse, mutect2
- RTL8A | c.212G>A p.R71H | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV66188463; called by muse, varscan2
- VAV1 | c.1542C>T p.N514= | Silent (SNP) | VAF 19/73 reads (26%) | catalogued as rs199798227; called by muse, mutect2, varscan2
- NLRP6 | chr11:278568 C>A | 5'Flank (SNP) | VAF 4/25 reads (16%) | called by mutect2, varscan2
